Surgical pathology report (de-identified scan), TCGA case TCGA-BK-A139, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-BK-A139-02A (Recurrent Tumor).

[page 1 of 2]
Final Surgical Pathology Report

Procedure:

Diagnosis

Vagina, bladder, and rectosigmoid, pelvic exenteration: Recurrent high-grade endometrioid endometrial adenocarcinoma with necrosis, forming a 7.5 cm right paravaginal mass involving the bladder and rectal walls; negative margins of excision.

Microscopic Description:

Microscopic examination was performed. A poorly-differentiated, necrotic adenocarcinoma is found to form a 7.5 cm greatest dimension mass lesion adjacent to the vagina which does not involve the vaginal mucosa surface. Carcinoma invades the peri-vesicular soft tissue but does not appear to involve the muscularis propria of the bladder. There is a nodular deposit of tumor on the bladder serosal surface which may represent a replaced lymph node. An additional tumor deposit is present within the soft tissue, which is also possibly an additional replaced lymph node. Carcinoma invades into but not through the muscularis propria of the rectum. The excisional margins are free of carcinoma.

Histologic type: Endometrioid endometrial adenocarcinoma, recurrent
Histologic grade: high-grade

Extent: Carcinoma invades the perivesicular soft tissue, the rectal wall including the muscularis propria of the bowel, and the perivaginal soft tissues.

Margins of resection: Negative

Vascular invasion: Identified

Regional lymph nodes (pN): Four negative lymph nodes are identified within the specimen (0/4)

MSI testing: Ordered on block A8.

Specimen

Vagina, bladder, rectum and portion of sigmoid colon

1 CD - 0 - 3

adenocarcinoma, endometrioid, NOS

Site: Endometrium

8380/3

C54.1

Gross Description

Received fresh labeled "vagina, bladder, rectum and portion of sigmoid colon" is a previously unopened 11 cm segment of distal colon with an abundant amount of mesocolon, a 6.0 x 4.5 x 4.0 cm portion of residual tan-pink vaginal tissue and a 4.5 x 4.5 x 3.0 cm bladder. The perimeter of the urethra is inked black. The urethra is probe patent to the bladder lumen which is lined by diffusely edematous tan-pink mucosa. The infero-posterior bladder mucosa is slightly bosselated and tan-red. A left ureter segment measuring 3 cm in length and 0.25 cm in diameter is identified. A right ureter is not identified grossly. Posterior to the vagina corresponding roughly to the Pouch of Douglas is a retracted, fibrotic focus with subjacent induration. The surface is inked blue. The remainder of the surfaces surrounding the attached portion of vaginal tissue are also inked blue. The periphery of the vaginal mucosa is inked orange for identification purposes. The superior portion of vaginal mucosa is invaginated with an ill-defined, focally necrotic 3.0 x 2.5 cm tan-red-purple focus posteriorly. The proximal and distal margins of the segment of colon are 5.3 and 7.8 cm respectively. The colonic mucosa is dark grey with regular folds and the wall averages 0.5 cm. Occupying the central portion of the specimen is an ill-defined, soft focally necrotic tumor mass measuring 7.5 cm (superior to inferior) by 5.8 cm (right to left) by 5.5 cm

hw
10/26/12

[page 2 of 2]
A rubbery 1.5 x 1.0 x 0.3 cm tan-white nodule is identified along the posterior serosal surface of the bladder. A portion of tumor is submitted for tissue procurement as requested. A few slightly rubbery tan-pink-red tissues in keeping with lymph nodes measuring up to 0.3 cm are recovered from the associated adipose tissue. RS 14

Summary: 1 - urethra to bladder, 2 - posterior wall of bladder to tumor, 3 - left ureter margin and left ureteral orifice, 4 - tumor to inferolateral posterior vaginal margin, 5 - tumor to right lateral vaginal margin and surface of specimen, 6 - tumor to left vaginal margin and surface of specimen, 7 - tumor to anterosuperior vaginal margin, 8 and 9 - tumor to closest inked serosal surface, pouch of Douglas, 10 - proximal and distal margins rectal segment (proximal inked red), 11 and 12 - central rectal segment to subjacent tumor, 13 - nodule along serosal surface of bladder, 14 - lymph nodes

	Yes	No
any discrepancy		///
any change noted	///	///

Handwritten: *Recurrent*

Handwritten: *10/2/72*

Source: NCI Genomic Data Commons file 16c74aac-8ba9-40fa-a200-f5ddfe7072f4 (TCGA-BK-A139.FE6C557C-6F28-4F5C-B48C-E2A3BB7EF14F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).